Somatic mutation profile of tumor specimen TCGA-HC-A76W-01A (aliquot TCGA-HC-A76W-01A-11D-A33T-08) from TCGA case TCGA-HC-A76W, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.3 years (26,755 days).
Specimen TCGA-HC-A76W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a123206-3474-423d-9eb7-19cc6424d559.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A76W-10A (Blood Derived Normal), aliquot TCGA-HC-A76W-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ca2e09e-153b-4385-891c-b024321ace90

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE2 | c.768C>G p.I256M | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV53026275; called by muse, mutect2, varscan2
- AGAP6 | c.988A>T p.T330S (on ENST00000374056 / NM_001365867.1; = p.T353S on NM_001077665.2) | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100929116; called by muse, varscan2
- ARNTL2 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as COSV53824639, COSV99667957; called by muse, mutect2, varscan2
- B3GNT8 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV99524703; called by muse, mutect2, varscan2
- BPIFB1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs779716269, COSV53609919; called by muse, mutect2, varscan2
- CELF4 | c.878C>G p.A293G | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.313); catalogued as COSV100611872; called by muse, mutect2, varscan2
- DKK1 | c.523T>C p.S175P | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV100906563; called by muse, mutect2
- DYTN | c.625T>C p.W209R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV101123983; called by muse, mutect2, varscan2
- GALNT8 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771845589, COSV99363088; called by muse, mutect2, varscan2
- IFT122 | c.630T>G p.Y210* (on ENST00000348417 / NM_052989.3; = p.Y261* on NM_052985.4) | Nonsense Mutation (SNP) | VAF 34/115 reads (30%) | catalogued as COSV99959649; called by muse, mutect2, varscan2
- IKBKE | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs782278442, COSV65627051; called by muse, mutect2, varscan2
- KCNU1 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101299364; called by muse, mutect2, varscan2
- LY96 | c.229A>T p.N77Y | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99514571; called by muse, mutect2, varscan2
- MEGF10 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778835131, COSV57245863; called by muse, mutect2
- MYO1A | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749645697, COSV55657918; called by muse, mutect2, varscan2
- PCDHAC1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164923; called by muse, mutect2, varscan2
- ROBO2 | c.3431C>A p.S1144Y | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs757350469, COSV100168862, COSV59899442; called by muse, mutect2, varscan2
- RPF1 | c.787T>G p.F263V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV101035450; called by muse, mutect2, varscan2
- SIPA1L2 | c.2378A>C p.K793T | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99479174; called by muse, mutect2, varscan2
- SLAMF9 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); catalogued as COSV100928168, COSV63637040; called by muse, mutect2, varscan2
- SLC2A10 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376346077; called by muse, mutect2, varscan2
- STAC | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99830463; called by muse, mutect2, varscan2
- TARS3 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs762297869, COSV100254881; called by muse, mutect2, varscan2
- TJP3 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV99516368; called by muse, mutect2, varscan2
- TTN | c.84485G>A p.G28162E (on ENST00000591111; = p.G20738E on NM_003319.4) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | PolyPhen possibly damaging (0.758); catalogued as COSV100623229; called by muse, mutect2
- ZMYM3 | c.3462C>G p.N1154K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100078204; called by muse, mutect2, varscan2
- FAM186B | c.1220_1229del p.S407Mfs*11 | Frame Shift Del (DEL) | VAF 27/105 reads (26%) | called by mutect2, pindel, varscan2
- SCNN1B | c.804_806del p.Y269del | In Frame Del (DEL) | VAF 34/161 reads (21%) | called by mutect2, pindel, varscan2
- BMP4 | c.819C>T p.V273= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99817072; called by muse, mutect2, varscan2
- F2RL3 | c.189C>T p.L63= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as rs1440707094, COSV99935365; called by muse, mutect2
- IGLON5 | c.963G>A p.G321= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99570821; called by mutect2, varscan2
- MAGEB6 | c.609G>A p.A203= | Silent (SNP) | VAF 49/68 reads (72%) | catalogued as rs749588986, COSV66871905; called by muse, mutect2, varscan2
- NAP1L5 | c.501C>T p.A167= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as COSV99985836; called by muse, mutect2, varscan2
- RUNX3 | c.579G>A p.P193= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs773791670, COSV100137021; called by muse, mutect2, varscan2
- SLF1 | c.2622C>T p.D874= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs768716447, COSV54368288; called by muse, mutect2, varscan2
- TAL2 | c.291G>A p.Q97= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100482482, COSV61883701; called by muse, mutect2, varscan2
- UBASH3B | c.876C>T p.S292= | Silent (SNP) | VAF 68/233 reads (29%) | catalogued as rs373957579; called by muse, mutect2, varscan2
- AC244258.1 | n.787T>C | RNA (SNP) | VAF 8/28 reads (29%) | catalogued as rs1413392382; called by mutect2, varscan2
